Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7UH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7UH-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED] (Age: [REDACTED])
Physician(s): [REDACTED] M.D.
[REDACTED], M.D.

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

ICD-03
Carcinoma, squamous cell NOS
Site Cervix NOS
C53.9
8070/3
9/26/13

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY "A"
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, INVASIVE

UTERUS, CERVIX, BIOPSY "B"
- SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED, INVASIVE

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old woman with vaginal bleeding, exophytic mass from the cervix. Operative procedure: Cervical mass biopsy.

Specimen(s) Received:

A: CERVICAL MASS
B: CERVICAL MASS

Gross Description

The specimens are received in two containers of formalin, each labeled with the patient's name [REDACTED]. The first container is from the outside hospital, containing a fragment of tan-white tissue, measuring 0.4 x 0.4 x 0.3 cm. Labeled A1. Jar 0.

The second container is from [REDACTED], containing multiple fragments of tan-white to dark brown tissue, ranging from 0.3 x 0.1 x 0.1 cm to 0.7 x 0.4 x 0.2 cm. Labeled B1 and b2. Jar 0.

[REDACTED] M.D.

This Surgical Pathology report is available on-line on [REDACTED]

Physician Copy - [REDACTED]

HI/AA Discrepancy		

Source: NCI Genomic Data Commons file 9874711b-1bc5-4cb3-a85b-3e3b842c778d (TCGA-C5-A7UH.5D5876DB-6A68-4862-8982-8E15F26C9BF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).